Gene-level copy-number profile of tumor specimen TCGA-AN-A0AS-01A from TCGA case TCGA-AN-A0AS, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.2 years (25,658 days).
Specimen TCGA-AN-A0AS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.47150649-c6a6-48fc-a65c-bc621cbaec41.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0AS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eb73d796-4305-48a1-97bf-4320911e9fca

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,195; copy number 2: 10,230; copy number 3: 22,683; copy number 4: 18,079; copy number 5: 2,527; copy number 6: 1,248; copy number 7: 561; copy number 8: 1,305; copy number 9: 1,013; copy number 10: 378; copy number 11: 291; copy number 12: 111; copy number 13: 139; copy number 14: 29; copy number 15: 7; copy number 16: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0AS-01A-11D-A011-01): tumor purity 0.56, ploidy 3.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,856 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:201,283,452–202,592,706, 48 genes, copy number 7 (within-gene range 5–7): PKP1, TNNT2, AC119427.2, LAD1, AC119427.1, TNNI1, AC096677.3, PHLDA3, AC096677.2, CSRP1, AC096677.1, RPS10P7, NAV1, AC092800.1, IPO9-AS1, MIR5191, AL645504.1, RNU6-501P, MIR1231, IPO9, MIR6739, SHISA4, AL513217.1, LMOD1, TIMM17A, SNORA70H, RPL10P4, RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3, GPR37L1, ARL8A, PTPN7, PTPRVP, LGR6, UBE2T, PPP1R12B, CYCSP4, RNU6-89P, AC099336.1, AC099336.2, SNORA70.
- chr1:222,452,738–222,454,705, 1 gene, copy number 11: AL513314.1.
- chr6:55,106,460–55,579,197, 3 genes, copy number 7 (within-gene range 3–7): HCRTR2, GFRAL, HMGCLL1.
- chr6:63,719,980–65,707,226, 1 gene, copy number 7 (within-gene range 3–7): EYS.
- chr6:64,377,795–71,420,745, 61 genes, copy number 7–12 (broad region; genes not listed).
- chr6:78,604,467–79,703,655, 22 genes, copy number 7–12 (within-gene range 2–12): AL121718.1, AL450327.1, IRAK1BP1, PHIP, AL356776.1, AL356776.2, HMGN3, HMGN3-AS1, AL355796.1, Y_RNA, LCAL1, AL355379.1, AL078601.1, AL078601.2, AL391840.1, DBIP1, LCA5, AL391840.3, AL391840.2, AL451064.1, AL451064.2, SH3BGRL2.
- chr8:27,311,482–27,772,653, 15 genes, copy number 10 (within-gene range 1–10): PTK2B, MIR6842, CHRNA2, EPHX2, GULOP, CLU, MIR6843, SCARA3, RNU6-1086P, AC013643.1, AC013643.3, MIR3622B, MIR3622A, AC013643.2, CCDC25.
- chr8:41,261,962–41,309,473, 1 gene, copy number 10 (within-gene range 1–10): SFRP1.
- chr8:41,275,115–42,541,926, 36 genes, copy number 10 (within-gene range 1–10): AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 8–13 (broad region; genes not listed).
- chr9:26,746,953–27,297,150, 16 genes, copy number 7: AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN.
- chr9:31,644,576–31,645,160, 1 gene, copy number 7: HMGB3P23.
- chr9:35,038,625–36,487,548, 70 genes, copy number 7 (broad region; genes not listed).
- chr10:55,667,341–60,733,490, 37 genes, copy number 7 (within-gene range 5–7): GAPDHP21, AC069545.1, ZWINT, AC010996.1, AC025039.1, MIR3924, AL731534.1, AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10, CISD1, AC016396.1, AC016396.2, UBE2D1, TFAM, BICC1, FAM133CP, RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2.
- chr10:121,740,424–124,836,667, 61 genes, copy number 8–12 (within-gene range 5–12) (broad region; genes not listed).
- chr11:69,294,151–79,612,300, 318 genes, copy number 7–10 (broad region; genes not listed).
- chr12:18,358,443–18,358,967, 1 gene, copy number 12: NDFIP1P1.
- chr12:28,978,584–34,249,958, 119 genes, copy number 10–11 (broad region; genes not listed).
- chr12:41,188,320–42,238,349, 12 genes, copy number 7 (within-gene range 5–7): PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2.
- chr12:42,286,911–42,288,560, 1 gene, copy number 7: AC020629.1.
- chr12:62,466,817–70,920,738, 192 genes, copy number 7–15 (broad region; genes not listed).
- chr13:21,094,315–22,276,526, 29 genes, copy number 9: RPS12P23, IPPKP1, AL161613.1, SNORD27, SAP18, SKA3, MRPL57, AL158032.1, LINC01046, ESRRAP2, AL158032.2, MIPEPP3, LINC00539, GRK6P1, GAPDHP52, RNA5SP25, ZDHHC20, ZDHHC20-IT1, H2BP6, MICU2, FNTAP2, RNU6-59P, RPS7P10, FGF9, RN7SL766P, LINC00424, LINC00540, NME1P1, MTND3P1.
- chr13:24,408,157–25,210,295, 30 genes, copy number 10 (within-gene range 9–10): TPTE2P6, PARP4, AL359538.4, AL359538.3, PSPC1P2, AL359538.1, AL359538.2, ATP12A, RNY1P7, RPL26P34, AL391560.1, IRX1P1, AL391560.2, ANKRD20A10P, RNF17, CENPJ, TPTE2P1, AL354798.1, SLC25A15P3, RPL34P27, LSP1P1, AL590099.1, PABPC3, AL359757.2, AMER2, LINC01053, LINC00463, AL359757.1, LINC01076, RPL23AP69.
- chr13:27,792,483–31,053,250, 68 genes, copy number 11 (broad region; genes not listed).
- chr13:31,846,713–32,299,125, 1 gene, copy number 9 (within-gene range 6–9): FRY.
- chr13:31,975,167–41,981,565, 151 genes, copy number 7–16 (broad region; genes not listed).
- chr13:44,575,893–45,732,356, 34 genes, copy number 7: TSC22D1-AS1, SMARCE1P5, LINC00407, AL356515.1, LINC00330, NUFIP1, AL359706.1, GPALPP1, RN7SL49P, RN7SKP3, GTF2F2, RN7SKP4, AL138693.1, KCTD4, AL138963.2, TPT1, SNORA31B, SNORA31, AL138963.3, TPT1-AS1, AL138963.1, RCN1P2, SLC25A30, SLC25A30-AS1, PPIAP25, COG3, ERICH6B, RNA5SP27, TIMM9P3, COX4I1P2, LINC01055, AKR1B1P4, CBY2, Metazoa_SRP.
- chr14:75,574,888–106,875,071, 900 genes, copy number 9 (broad region; genes not listed).
- chr18:26,655,737–27,795,637, 18 genes, copy number 8 (within-gene range 4–8): AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1.
- chr20:34,363,241–34,540,748, 1 gene, copy number 11 (within-gene range 4–11): ITCH.
- chr20:34,450,930–36,270,918, 74 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,195. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
